Somatic mutation profile of tumor specimen TCGA-DA-A95V-06A (aliquot TCGA-DA-A95V-06A-11D-A372-08) from TCGA case TCGA-DA-A95V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 86.7 years (31,677 days).
Specimen TCGA-DA-A95V-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 318c7710-5f0b-4bf9-9b4a-25a4cd24f668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A95V-10A (Blood Derived Normal), aliquot TCGA-DA-A95V-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede000f8-248e-46be-917c-571096fcfa59

The open-access MAF lists 316 somatic variants for this specimen: 210 protein-altering or splice-affecting, 98 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 98, Nonsense Mutation 12, Intron 3, Splice Site 3, Splice Region 2, RNA 2, Frame Shift Del 2, 3'UTR 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.3717G>A p.Q1239= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100228917; called by muse, mutect2, varscan2
- ABCA9 | c.3319C>T p.Q1107* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as rs866313581, COSV100383096; called by muse, mutect2, varscan2
- ABCG2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV99419217; called by muse, mutect2, varscan2
- ACSL4 | c.761G>A p.G254E (on ENST00000340800 / NM_022977.2; = p.G213E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100538544; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1176728595, COSV65892385; called by muse, mutect2, varscan2
- ALB | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs748640859, COSV55735636; called by muse, mutect2, varscan2
- ALDH18A1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100973166; called by muse, mutect2, varscan2
- ALPK2 | c.5773T>G p.F1925V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100864353; called by muse, mutect2, varscan2
- ALPK2 | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs772550142, COSV100864356, COSV64492813; called by muse, mutect2, varscan2
- ANKRD30A | c.3913G>A p.E1305K (on ENST00000611781; = p.E1249K on NM_052997.2) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs867764777, COSV64614680, COSV64619316; called by muse, mutect2, varscan2
- AQP5 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 23/40 reads (58%) | catalogued as rs1349801845, COSV99527474; called by muse, mutect2, varscan2
- ARHGEF12 | c.2137T>A p.F713I | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100754904; called by muse, mutect2, varscan2
- ARHGEF2 | c.2090C>T p.P697L (on ENST00000361247 / NM_001162383.2; = p.P669L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100560561; called by muse, mutect2, varscan2
- ARHGEF2 | c.2089C>G p.P697A (on ENST00000361247 / NM_001162383.2; = p.P669A on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as rs767426471, COSV100560565; called by muse, mutect2, varscan2
- ATP10B | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); catalogued as rs776311658, COSV100514922; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023094; called by muse, mutect2, varscan2
- ATRX | c.4775T>G p.L1592R | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970729, COSV64885833; called by muse, mutect2, varscan2
- BDP1 | c.7355C>T p.P2452L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100703056; called by muse, mutect2
- BICC1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99570508; called by muse, mutect2, varscan2
- BTNL3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100732206; called by muse, mutect2, varscan2
- C3orf38 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as rs1403431757, COSV100007401; called by muse, mutect2, varscan2
- C6 | c.2370A>C p.E790D | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV99667046; called by muse, mutect2, varscan2
- CACNG3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1417412443, COSV50066657; called by muse, mutect2, varscan2
- CALR3 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 83/136 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV54168251, COSV99522178; called by muse, mutect2, varscan2
- CAPN13 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV54429286; called by muse, mutect2, varscan2
- CCDC148 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV99320424; called by muse, mutect2, varscan2
- CD72 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 52/86 reads (60%) | catalogued as COSV52412409; called by muse, mutect2, varscan2
- CDH7 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100542319, COSV59893882; called by muse, mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by muse, mutect2, varscan2
- CES2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs752262052, COSV100399070; called by muse, mutect2, varscan2
- CGNL1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV99848248; called by muse, mutect2, varscan2
- CLDND2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389875; called by muse, mutect2, varscan2
- CLK4 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV60318126, COSV60320843; called by muse, mutect2
- CLPTM1 | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.037); catalogued as COSV100493767; called by muse, mutect2, varscan2
- CLUAP1 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100489652; called by muse, mutect2, varscan2
- CNTNAP2 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as rs267601388, COSV62143231, COSV62177141; called by muse, mutect2, varscan2
- COL6A3 | c.9231G>A p.K3077= | Splice Region (SNP) | VAF 15/37 reads (41%) | catalogued as COSV55082584, COSV99798214; called by muse, mutect2, varscan2
- COLEC12 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101232065; called by muse, mutect2, varscan2
- CPAMD8 | c.4696G>A p.G1566R (on ENST00000651564; = p.G1519R on NM_015692.5) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1464404129, COSV101488512; called by muse, mutect2, varscan2
- CTNNA2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766045574, COSV63560688; called by muse, mutect2, varscan2
- CTNND2 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100476376; called by muse, mutect2
- CYP2C9 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs1253597502, COSV99582685; called by muse, mutect2, varscan2
- DAW1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV100006174; called by muse, mutect2, varscan2
- DCDC1 | c.3847G>A p.E1283K (on ENST00000597505 / NM_001367979.1; = p.E390K on NM_020869.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100338224; called by muse, mutect2, varscan2
- DCTN1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1242262007, COSV100720946; called by muse, mutect2, varscan2
- DNAH5 | c.5508G>A p.M1836I | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54222664, COSV54244587; called by muse, mutect2, varscan2
- DPYD | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100929033; called by muse, mutect2, varscan2
- DSG3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs142415015; called by muse, mutect2, varscan2
- DSG4 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs868142301, COSV57392836; called by muse, mutect2, varscan2
- ECI2 | c.626C>T p.P209L (on ENST00000380118 / NM_206836.3; = p.P179L on NM_006117.2) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV100326470; called by muse, mutect2, varscan2
- EDN3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100284909; called by muse, mutect2, varscan2
- ENPEP | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560548080, COSV54455446; called by muse, mutect2, varscan2
- EPHA3 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs759709969, COSV100345112; called by muse, mutect2, varscan2
- ERG | c.210G>T p.R70S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1438907930, COSV99901871; called by muse, mutect2, varscan2
- EXOC3L2 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1328637962, COSV52974186; called by muse, mutect2, varscan2
- EXOSC7 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV99652012; called by muse, mutect2, varscan2
- EXT2 | c.1289A>G p.N430S (on ENST00000343631; = p.N463S on NM_000401.3) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs773676927, COSV100640606; called by muse, mutect2, varscan2
- EYA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58159030; called by muse, mutect2, varscan2
- FAAH2 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs763856122, COSV66512186; called by muse, mutect2, varscan2
- FABP12 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs374133627; called by muse, mutect2, varscan2
- FAM98B | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs1468780077, COSV99989098; called by muse, mutect2, varscan2
- FCN1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 91/134 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs777571891, COSV65662178; called by muse, mutect2, varscan2
- FGFR4 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs139461102; called by muse, varscan2
- FILIP1 | c.3535G>A p.G1179R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs777887172, COSV99384771; called by muse, mutect2, varscan2
- FREM2 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs201063766, COSV54844085; called by muse, mutect2, varscan2
- GHDC | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as COSV100054695; called by muse, mutect2, varscan2
- GLT8D2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99904166; called by muse, mutect2, varscan2
- GMPR | c.381C>G p.C127W | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99440120, COSV99440515; called by muse, mutect2, varscan2
- GOLT1A | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100383471; called by muse, mutect2, varscan2
- GPRIN3 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100310576, COSV100310731; called by muse, mutect2, varscan2
- GRIK2 | c.2450T>C p.V817A | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV59716428; called by muse, mutect2, varscan2
- GRIN2A | c.3639C>A p.H1213Q | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100409739; called by muse, mutect2, varscan2
- GTF3C1 | c.4102A>C p.K1368Q | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1416077769, COSV100649395; called by muse, mutect2, varscan2
- GTF3C1 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs201119327, COSV100649396; called by muse, mutect2, varscan2
- HLA-C | c.894G>T p.W298C | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs281860573, COSV100880553; called by muse, mutect2, varscan2
- HM13 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as rs772766988, COSV100159495; called by muse, mutect2, varscan2
- IGSF22 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100079735; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV100781258; called by muse, mutect2, varscan2
- JUND | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417205; called by muse, mutect2, varscan2
- KAZN | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1191998283, COSV101055625; called by muse, mutect2
- KCNH6 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); catalogued as rs1241642457, COSV100121012; called by muse, mutect2, varscan2
- KDR | c.3322G>T p.G1108W | Missense Mutation (SNP) | VAF 21/487 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55764524; called by muse, mutect2
- KIR2DL4 | c.322C>T p.P108S (on ENST00000396284; = p.P69S on NM_001080770.2) | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.535); catalogued as rs886782247; called by muse, mutect2, varscan2
- KLF15 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1160068070, COSV56181096; called by muse, mutect2, varscan2
- KMT2B | c.5174C>G p.P1725R | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99719571; called by muse, mutect2
- LRP1B | c.9121G>A p.G3041R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101258174, COSV67221398; called by muse, mutect2, varscan2
- LRP2 | c.8983G>A p.E2995K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.229); catalogued as COSV99788369; called by muse, mutect2, varscan2
- LRP2 | c.6078G>A p.M2026I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99788372, COSV99789785; called by muse, mutect2, varscan2
- LRRC30 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV67302378; called by muse, mutect2, varscan2
- LRRC37B | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100496262; called by muse, mutect2, varscan2
- LRRC37B | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100496264; called by muse, mutect2, varscan2
- LRRK2 | c.6785T>A p.F2262Y | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100110142; called by muse, mutect2, varscan2
- LSM14B | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1358506729, COSV53379826; called by muse, mutect2, varscan2
- MAD2L1BP | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100937792, COSV100937817; called by muse, mutect2, varscan2
- MAGED2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1200366548, COSV54497477; called by muse, mutect2, varscan2
- MARVELD2 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57782921; called by muse, mutect2, varscan2
- MPO | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV56568161, COSV99832640; called by muse, mutect2, varscan2
- MS4A15 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100558880; called by muse, mutect2
- MSRB1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770828953, COSV99238235; called by muse, mutect2, varscan2
- MUC17 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1348183116, COSV100073147; called by muse, mutect2, varscan2
- MYH13 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV52825811; called by muse, mutect2
- MYH4 | c.5262T>G p.N1754K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV99701238; called by muse, mutect2, varscan2
- MYO5B | c.2653G>C p.D885H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99544825; called by muse, mutect2, varscan2
- NCKAP1L | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53206265; called by muse, mutect2, varscan2
- NEUROD4 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as COSV54470915; called by muse, mutect2, varscan2
- NF1 | c.4986G>A p.W1662* (on ENST00000358273 / NM_001042492.3; = p.W1641* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV55985616; called by muse, mutect2, varscan2
- NFAT5 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100590777; called by muse, mutect2, varscan2
- NLRP10 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762414203, COSV60778851; called by muse, mutect2, varscan2
- NTN4 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs377286047; called by muse, mutect2, varscan2
- NUB1 | c.1541C>T p.P514L (on ENST00000568733 / NM_001243351.1; = p.P500L on NM_016118.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as rs1563032684, COSV100879274; called by muse, mutect2, varscan2
- NUP98 | c.2609C>G p.T870S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV100262341; called by muse, mutect2, varscan2
- OGT | c.1065+1G>A p.X355_splice | Splice Site (SNP) | VAF 54/105 reads (51%) | catalogued as COSV101035388; called by muse, mutect2, varscan2
- OR13C9 | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV52241290; called by muse, mutect2, varscan2
- OR14A16 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100713777; called by muse, mutect2, varscan2
- OR4K2 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 76/118 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as rs1044297225, COSV53848142; called by muse, mutect2, varscan2
- OR51B4 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as rs1169700786, COSV100971268, COSV66518035; called by muse, mutect2
- OSBPL8 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as rs1019475721, COSV99675025; called by muse, varscan2
- OSTF1 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100653713; called by muse, mutect2, varscan2
- OTOL1 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 31/33 reads (94%) | catalogued as COSV100019974; called by muse, mutect2, varscan2
- PADI3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100968478; called by muse, mutect2, varscan2
- PAK5 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs768724288, COSV62021696; called by muse, mutect2, varscan2
- PCLO | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369616405, COSV100432355; called by muse, mutect2, varscan2
- PDE1A | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100114242, COSV59518500; called by muse, mutect2, varscan2
- PDYN | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99453006; called by muse, mutect2, varscan2
- PELP1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1346450598, COSV99342837; called by muse, mutect2, varscan2
- PHLDB2 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101208517; called by muse, mutect2, varscan2
- PIGR | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs775192099, COSV100732509; called by muse, mutect2, varscan2
- PIK3AP1 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100225756; called by muse, mutect2, varscan2
- PITPNM1 | c.293+1G>A p.X98_splice | Splice Site (SNP) | VAF 42/65 reads (65%) | catalogued as COSV100039388; called by muse, mutect2, varscan2
- PKHD1L1 | c.9395G>A p.G3132E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752265969, COSV65748973; called by muse, mutect2
- PKHD1L1 | c.11845G>A p.E3949K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV65742584, COSV65752827; called by muse, mutect2, varscan2
- PLA2G4D | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99299671; called by muse, mutect2, varscan2
- PLEKHG4B | c.989A>C p.D330A (on ENST00000283426; = p.D686A on NM_052909.5) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99360265; called by muse, mutect2, varscan2
- PLXNB1 | c.5935A>T p.N1979Y | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602818; called by muse, mutect2, varscan2
- PMEL | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV100093054; called by muse, mutect2, varscan2
- PNPLA7 | c.2965G>A p.G989S | Missense Mutation (SNP) | VAF 65/91 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.209); catalogued as rs1299464272, COSV99480618; called by muse, mutect2, varscan2
- PRAMEF14 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1306384711; called by muse, mutect2, varscan2
- PRDM9 | c.248T>A p.L83H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.57); catalogued as COSV57009721, COSV99690418; called by muse, mutect2, varscan2
- PREP | c.1708C>T p.L570F (on ENST00000369110; = p.L636F on NM_002726.5) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV100963925; called by muse, mutect2, varscan2
- PRKAA2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 150/234 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100982825; called by muse, mutect2, varscan2
- PRKCB | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867836631, COSV100333946; called by muse, mutect2, varscan2
- PTPRE | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV99617841; called by muse, mutect2, varscan2
- RBL1 | c.1230C>G p.D410E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100727038; called by muse, varscan2
- RDH16 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100660108; called by muse, mutect2
- RNASE10 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs375918997; called by muse, mutect2, varscan2
- ROBO2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100166633; called by muse, mutect2, varscan2
- RRP15 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV65117929; called by muse, mutect2, varscan2
- RTTN | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99732300; called by muse, mutect2, varscan2
- SAMD14 | c.884C>T p.P295L (on ENST00000330175 / NM_001257359.2; = p.P323L on NM_174920.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV99142949; called by muse, mutect2, varscan2
- SAMD8 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101014051; called by muse, mutect2, varscan2
- SCAF11 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101014340; called by muse, mutect2, varscan2
- SDK1 | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67359929; called by muse, mutect2, varscan2
- SELENOP | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV101539869; called by muse, mutect2, varscan2
- SGCZ | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs138916610; called by muse, mutect2, varscan2
- SHROOM4 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs782131154, COSV99173512; called by muse, mutect2, varscan2
- SLC16A11 | c.1339G>A p.G447R (on ENST00000308009; = p.G423R on NM_153357.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs763906625, COSV100338626; called by muse, mutect2, varscan2
- SLC16A6 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs1555749368, COSV59177380; called by muse, mutect2
- SLC17A3 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1384180198, COSV100399210, COSV57760101; called by muse, mutect2, varscan2
- SLC27A6 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1248096753, COSV52487427; called by muse, mutect2, varscan2
- SLC38A11 | c.919G>A p.E307K (on ENST00000409149 / NM_001351539.1; = p.E285K on NM_173512.2) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100366864; called by muse, mutect2, varscan2
- SLC5A11 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1294089261, COSV100762789; called by muse, mutect2, varscan2
- SLC6A16 | c.1658T>A p.F553Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100242730; called by muse, mutect2
- SLC6A6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400003153, COSV62649266; called by muse, mutect2, varscan2
- SLCO1B1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV57009976; called by muse, mutect2, varscan2
- SLIT1 | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.691); catalogued as COSV99821345; called by muse, mutect2
- SLITRK1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65674844; called by muse, mutect2, varscan2
- SPAG17 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100309045; called by muse, mutect2, varscan2
- SPHKAP | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs774693604, COSV60875248; called by muse, mutect2, varscan2
- SPHKAP | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60869360; called by muse, mutect2, varscan2
- SPTBN5 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV58018449; called by muse, mutect2, varscan2
- STYXL2 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99609179; called by muse, mutect2, varscan2
- TAF1 | c.816G>A p.W272* (on ENST00000373790 / NM_138923.4; = p.W293* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99335668; called by muse, mutect2, varscan2
- TBC1D8B | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756915857, COSV99344374; called by muse, mutect2, varscan2
- THADA | c.5120C>T p.T1707I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100368608; called by muse, mutect2, varscan2
- THSD4 | c.1246G>C p.G416R | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965526; called by muse, mutect2, varscan2
- TNRC6C | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1472891048, COSV100049981; called by muse, mutect2, varscan2
- TNS3 | c.4022A>G p.E1341G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100235513; called by muse, mutect2
- TRIOBP | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); catalogued as COSV60373935; called by muse, varscan2
- TTN | c.65824A>C p.T21942P (on ENST00000591111; = p.T14518P on NM_003319.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | PolyPhen benign (0.122); catalogued as COSV100611828; called by muse, mutect2, varscan2
- TTN | c.4856C>T p.S1619F (on ENST00000591111; = p.S1573F on NM_003319.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | PolyPhen probably damaging (0.93); catalogued as COSV100611835; called by muse, mutect2, varscan2
- UCK2 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100902966, COSV100902967; called by muse, mutect2, varscan2
- UCK2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100902968; called by muse, mutect2, varscan2
- UGGT2 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs765341836, COSV65075080; called by muse, mutect2, varscan2
- ULK2 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs572303038, COSV100860802; called by muse, mutect2, varscan2
- UNC13A | c.4597C>T p.H1533Y | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV53190020; called by muse, mutect2, varscan2
- UNC5D | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV54827574, COSV99775090; called by muse, mutect2, varscan2
- UQCRB | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs751168289, COSV54629990; called by muse, mutect2, varscan2
- USP33 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100657107; called by muse, mutect2, varscan2
- USP6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.428); catalogued as rs201674756, COSV51472972; called by muse, mutect2, varscan2
- VOPP1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99567205; called by muse, mutect2, varscan2
- WDR36 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV72605043; called by muse, mutect2, varscan2
- WDR62 | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs771618020, COSV54333969, COSV54336030; called by muse, mutect2, varscan2
- ZAN | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs368072574, COSV61804642; called by muse, mutect2, varscan2
- ZBED9 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV71729617; called by muse, mutect2, varscan2
- ZFP91 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV100284513; called by muse, mutect2, varscan2
- ZHX2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201126119, COSV100073041; called by muse, mutect2, varscan2
- ZNF100 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99973992; called by muse, mutect2, varscan2
- ZNF135 | c.1036C>G p.R346G (on ENST00000313434 / NM_001289401.2; = p.R358G on NM_003436.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536601; called by muse, mutect2, varscan2
- ZNF28 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as COSV100354485; called by muse, mutect2, varscan2
- ZNF407 | c.5704G>A p.V1902M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768065743, COSV100225739; called by muse, mutect2, varscan2
- ZPR1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV99911315; called by muse, mutect2, varscan2
- DDX4 | c.914_921del p.K305Ifs*3 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel
- FCGBP | c.12303G>A p.M4101I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GGNBP2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSF2BP | c.391_393delinsC p.W132Gfs*6 | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | called by pindel, varscan2*
- NF1 | c.5269-10_5279del p.X1757_splice (on ENST00000358273 / NM_001042492.3; = p.X1736_splice on NM_000267.3) | Splice Site (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel
- PLEC | c.13088_13114del p.T4363_D4371del (on ENST00000322810 / NM_201380.4; = p.T4253_D4261del on NM_000445.5) | In Frame Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel
- POLR2A | c.4819G>T p.G1607C | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRAMEF15 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 90/1169 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.439); called by muse, mutect2
- PRAMEF19 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 50/962 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.495); called by muse, mutect2
- ABCG2 | c.1506G>A p.K502= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs757288072, COSV99419223; called by muse, mutect2, varscan2
- AC100868.1 | c.1416C>T p.T472= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs781696751, COSV99226041; called by muse, varscan2
- ACTG2 | c.390C>T p.V130= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100609160; called by muse, mutect2, varscan2
- ADAMTS18 | c.684C>T p.S228= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs753689650, COSV51411607; called by muse, mutect2, varscan2
- ADGRB1 | c.1848T>C p.C616= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100029643; called by muse, mutect2, varscan2
- ADGRG4 | c.5739C>T p.H1913= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs774475338, COSV99795405; called by muse, varscan2
- ADGRG4 | c.6042C>T p.L2014= | Silent (SNP) | VAF 52/93 reads (56%) | catalogued as rs746164623, COSV99795407; called by muse, mutect2, varscan2
- AGRN | c.4908C>T p.F1636= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as rs773269271, COSV101038831; called by muse, mutect2, varscan2
- ALPK2 | c.5772C>T p.H1924= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1568072069, COSV100864354; called by muse, mutect2, varscan2
- AMDHD1 | c.798G>A p.P266= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs376460465; called by muse, mutect2, varscan2
- APBA1 | c.1095C>T p.I365= | Silent (SNP) | VAF 71/100 reads (71%) | catalogued as rs1427187183, COSV99596046; called by muse, mutect2, varscan2
- ARHGEF11 | c.3498C>T p.C1166= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1043447158, COSV100168590; called by muse, mutect2, varscan2
- AXIN2 | c.1080G>A p.K360= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100196479; called by muse, mutect2, varscan2
- C17orf80 | c.1423C>T p.L475= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV99278064; called by muse, mutect2, varscan2
- C2orf68 | c.141C>T p.A47= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100083785; called by muse, mutect2
- CACHD1 | c.291C>T p.N97= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as COSV99262241; called by muse, mutect2, varscan2
- CACNG3 | c.831G>A p.G277= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV99136110; called by muse, mutect2, varscan2
- CDYL2 | c.1078C>T p.L360= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV101629559; called by muse, mutect2, varscan2
- CHD5 | c.666C>T p.I222= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99313532; called by muse, mutect2, varscan2
- CNTNAP5 | c.3747C>T p.F1249= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs1298713089, COSV70479018; called by muse, mutect2, varscan2
- CPAMD8 | c.3357C>T p.V1119= (on ENST00000651564; = p.V1072= on NM_015692.5) | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV101488513; called by muse, mutect2, varscan2
- CYP2C9 | c.195C>T p.F65= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV99582678; called by muse, mutect2, varscan2
- CYP2C9 | c.753C>T p.H251= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs755804202, COSV99582680; called by muse, mutect2, varscan2
- DMD | c.10926G>A p.E3642= | Silent (SNP) | VAF 48/80 reads (60%) | catalogued as COSV100627199; called by muse, mutect2, varscan2
- DNAH11 | c.1548A>G p.K516= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV100179202; called by muse, mutect2, varscan2
- DNAH17 | c.267G>A p.K89= | Silent (SNP) | VAF 57/118 reads (48%) | catalogued as COSV67758469; called by muse, mutect2, varscan2
- DPPA2 | c.510A>G p.E170= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV101524761, COSV72118258; called by muse, mutect2, varscan2
- DSG3 | c.1149C>T p.F383= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV99934145; called by muse, mutect2, varscan2
- DUSP8 | c.102C>T p.S34= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs1383120503, COSV59029637; called by muse, mutect2, varscan2
- ELP5 | c.570G>A p.L190= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63039037; called by muse, mutect2, varscan2
- FAM135B | c.798C>T p.I266= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99423739; called by muse, mutect2, varscan2
- FBLN7 | c.309C>A p.V103= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100485542; called by muse, mutect2, varscan2
- GAD1 | c.585G>A p.L195= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100713813; called by muse, mutect2, varscan2
- GBP1 | c.798A>T p.V266= | Silent (SNP) | VAF 72/112 reads (64%) | catalogued as COSV100976258; called by muse, mutect2, varscan2
- H3-5 | c.60G>A p.Q20= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV100461652; called by muse, mutect2, varscan2
- HNF1B | c.1152C>T p.V384= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- KAZN | c.2001C>T p.L667= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1487089997, COSV101055623; called by muse, mutect2
- KCNG1 | c.1173C>T p.F391= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1457867165, COSV65368880; called by muse, mutect2, varscan2
- KCNK17 | c.309C>T p.L103= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs759291342, COSV64678053; called by muse, mutect2, varscan2
- KIF21B | c.1083C>T p.L361= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100144501; called by muse, mutect2, varscan2
- KLF8 | c.492C>T p.P164= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs758685449, COSV100808235; called by muse, mutect2, varscan2
- LCT | c.3156C>T p.T1052= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs765069897, COSV99929447; called by muse, mutect2, varscan2
- MUC16 | c.28755G>A p.L9585= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV101199878; called by muse, mutect2, varscan2
- MYH11 | c.414C>T p.I138= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs1162127083, COSV55554063; called by muse, mutect2, varscan2
- MYH2 | c.3657G>A p.V1219= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs868372073, COSV55431603; called by muse, mutect2, varscan2
- MYH7 | c.4164G>A p.E1388= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as COSV100806085; called by muse, mutect2
- MYH8 | c.4350G>A p.R1450= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV101238027; called by muse, mutect2, varscan2
- NAB1 | c.93C>T p.I31= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100492989; called by muse, mutect2, varscan2
- NPHS1 | c.1095C>T p.S365= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100799842; called by muse, mutect2
- ODAM | c.270G>A p.Q90= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV101258049, COSV68573040; called by muse, mutect2, varscan2
- OR2T3 | c.354C>T p.F118= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1227039275, COSV62082604; called by mutect2, varscan2
- OR4Q3 | c.282C>T p.F94= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV59177427; called by muse, mutect2, varscan2
- PCDHB4 | c.873C>T p.F291= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as COSV99522172; called by muse, mutect2, varscan2
- PCLO | c.8262G>A p.V2754= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV61620003; called by muse, mutect2, varscan2
- PCLO | c.2682G>A p.Q894= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV100432357; called by muse, mutect2, varscan2
- PDE8B | c.1320C>T p.S440= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99366756; called by muse, mutect2
- PLB1 | c.24C>T p.F8= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs1366886943, COSV59822884; called by muse, mutect2, varscan2
- PLCXD3 | c.669G>A p.E223= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100125719; called by muse, mutect2, varscan2
- PLXNB1 | c.5934C>A p.T1978= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as COSV99602820; called by muse, mutect2, varscan2
- PMEL | c.540C>G p.G180= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100093056; called by muse, mutect2, varscan2
- PPP1R3D | c.480G>A p.P160= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs750924836, COSV100674518; called by muse, mutect2, varscan2
- PRCP | c.159C>T p.F53= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1304704830, COSV100475952; called by muse, mutect2, varscan2
- RASGRF2 | c.1476G>A p.E492= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99429186; called by muse, mutect2, varscan2
- RDH16 | c.396C>T p.T132= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100660107; called by muse, mutect2
- ROBO2 | c.2022G>A p.Q674= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as COSV100166635; called by muse, mutect2, varscan2
- SCAF11 | c.1827C>A p.P609= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV101014342; called by muse, mutect2, varscan2
- SDK1 | c.3594G>A p.P1198= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs775204533, COSV101269355; called by muse, mutect2, varscan2
- SGSM2 | c.1206C>T p.S402= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs938722361, COSV99280125; called by muse, mutect2, varscan2
- SIRT4 | c.330C>T p.F110= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs375219114; called by muse, mutect2, varscan2
- SLC13A1 | c.1290C>T p.F430= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV99520882; called by muse, mutect2, varscan2
- SLC36A3 | c.888C>T p.I296= | Silent (SNP) | VAF 75/186 reads (40%) | catalogued as rs777948806, COSV100077616, COSV58857714; called by muse, mutect2, varscan2
- SLC38A1 | c.697C>T p.L233= | Silent (SNP) | VAF 115/182 reads (63%) | catalogued as COSV101284180; called by muse, mutect2, varscan2
- SLC6A16 | c.1659C>T p.F553= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100242727; called by muse, mutect2
- STAU1 | c.573G>A p.E191= (on ENST00000371856 / NM_001319135.1; = p.E110= on NM_004602.3) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100574352; called by muse, mutect2, varscan2
- TACR1 | c.348C>T p.V116= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs1431707401, COSV100537895; called by muse, mutect2, varscan2
- TAF1L | c.5421C>T p.P1807= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99644638; called by muse, mutect2, varscan2
- TAS2R16 | c.441G>A p.G147= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99972210; called by muse, mutect2, varscan2
- TFDP3 | c.471G>A p.V157= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100033371; called by muse, mutect2, varscan2
- TNS1 | c.372C>T p.I124= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs765160698, COSV99410651; called by muse, mutect2, varscan2
- TRBV27 | c.246G>A p.G82= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs1019001735; called by muse, mutect2, varscan2
- TSHZ2 | c.2586G>A p.S862= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs746681566, COSV61592109; called by muse, mutect2, varscan2
- TSPYL6 | c.1017C>T p.F339= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs867939731, COSV100336586; called by muse, mutect2, varscan2
- TTN | c.12888G>A p.V4296= (on ENST00000591111; = p.V4250= on NM_003319.4) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1307850717, COSV100611832; called by muse, mutect2, varscan2
- TTN | c.8817C>T p.I2939= (on ENST00000591111; = p.I2893= on NM_003319.4) | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs751884113, COSV100611834; called by muse, mutect2, varscan2
- TTR | c.366C>T p.P122= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99379524; called by muse, mutect2, varscan2
- UPK2 | c.69G>A p.G23= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99875024; called by muse, mutect2, varscan2
- USH1C | c.1074G>A p.K358= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV50014898; called by muse, mutect2, varscan2
- USHBP1 | c.1014G>A p.E338= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV99394218; called by muse, mutect2, varscan2
- USP8 | c.1941C>T p.I647= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs747926929, COSV100208597; called by muse, mutect2, varscan2
- VRTN | c.1365C>T p.A455= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99832237; called by muse, mutect2, varscan2
- ZDBF2 | c.490C>T p.L164= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100984651, COSV100984816; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1947C>T p.F649= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs1214107270, COSV60157098; called by muse, mutect2, varscan2
- ZMYM3 | c.486C>T p.T162= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100077855; called by muse, mutect2, varscan2
- ZNF229 | c.1851C>T p.I617= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99350397; called by muse, mutect2, varscan2
- ZNF626 | c.1230T>C p.S410= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- ZNF81 | c.1773C>T p.F591= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100095609; called by muse, mutect2, varscan2
- ZRANB3 | c.1467C>T p.F489= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51511269; called by muse, mutect2, varscan2
- ZSWIM2 | c.1518G>A p.G506= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs930392249, COSV54574423; called by muse, mutect2, varscan2
- DCHS2 | n.750G>A | RNA (SNP) | VAF 43/78 reads (55%) | catalogued as COSV59735477; called by muse, mutect2, varscan2
- GPX5 | c.*1G>A | 3'UTR (SNP) | VAF 9/37 reads (24%) | catalogued as rs1245399989, COSV101297261; called by muse, mutect2, varscan2
- KDELR2 | c.*105C>T | 3'UTR (SNP) | VAF 66/102 reads (65%) | catalogued as rs752285342, COSV51726426, COSV99330558; called by muse, mutect2, varscan2
- NACA | c.71-4263C>T | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100771315; called by muse, mutect2, varscan2
- NFASC | c.2470+2081G>A | Intron (SNP) | VAF 9/37 reads (24%) | catalogued as rs766660732, COSV58380797; called by muse, mutect2, varscan2
- NRXN3 | c.602-5374G>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as rs1567907409, COSV99818697; called by muse, mutect2, varscan2
- NSG2 | c.-2G>A | 5'UTR (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100292812; called by muse, mutect2, varscan2
- SNORD115-31 | n.34G>A | RNA (SNP) | VAF 105/431 reads (24%) | catalogued as rs780757353; called by muse, mutect2, varscan2
